Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAEX, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAEX-01A (Primary Tumor).

Department of Pathology

ICD O-3
Seminoma NOS 9061/3
Site ① Testis C62.9
9w 3/3/14

Direct dial

Mobile: -

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 7 cm; no angio-invasion present; no invasion of rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file eaed4526-c3be-4f91-836f-07f882e99cc2 (TCGA-2G-AAEX.1487775D-C02B-44EA-BDEC-C261A6914391.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).